Gene-level copy-number profile of tumor specimen ALCH-B3E8-TTP1-A from ALCHEMIST case ALCH-B3E8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,820 days).
Specimen ALCH-B3E8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 169e80f2-f406-46ec-8a75-b74fb8f781e1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3E8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/970ca2fa-94ad-47d7-94b7-b430e111a968

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 36; copy number 2: 58,194; copy number 3: 61; copy number 4: 10; copy number 5: 44; copy number 6: 23; copy number 8: 9; copy number 10: 11; copy number 13: 3; copy number 14: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,515,997–130,658,037, 9 genes, copy number 5: AC013269.2, Metazoa_SRP, CFC1B, AC013269.1, PRSS40B, CFC1, Metazoa_SRP, POTEJ, RNU6-848P.
- chr12:57,693,955–57,984,761, 27 genes, copy number 5: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:60,092,864–60,419,293, 6 genes, copy number 5–8: AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:66,950,754–67,132,205, 3 genes, copy number 13: AC073530.1, AC073530.2, RAB11AP2.
- chr12:68,805,011–70,543,040, 40 genes, copy number 6–14 (within-gene range 4–14): AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1.
- chr12:71,125,085–71,586,310, 4 genes, copy number 6: TSPAN8, LGR5, AC090116.1, AC078860.3.
- chr12:72,087,266–72,728,844, 5 genes, copy number 5 (within-gene range 2–5): TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:73,648,666–73,846,188, 4 genes, copy number 5–8: AC087879.1, RNU6-1012P, LINC02445, U8.
- chr12:73,906,940–73,919,337, 1 gene, copy number 5: AC136188.1.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
